Gene-level copy-number profile of specimen HCM-SANG-1306-C25-85A-01D-A80T-32 from HCMI case HCM-SANG-1306-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G3.
Specimen HCM-SANG-1306-C25-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b97bb3d8-e7ae-4b52-801a-f53dac122096.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1306-C25-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/d950a14f-f53d-4fbe-b3b6-7aa45dd48f32

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,808; copy number 2: 16,015; copy number 3: 32,201; copy number 4: 7,200; copy number 5: 1,101; copy number 6: 40; copy number 7: 4; copy number 9: 12; copy number 10: 23.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 39 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:37,858,618–38,853,028, 39 genes, copy number 7–10: RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2.

Autosomal genes at a single copy (total copy number 1): 544. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
